Somatic mutation profile of tumor specimen TARGET-15-SJMPAL042789-09A.3 (aliquot TARGET-15-SJMPAL042789-09A.3-01D) from TARGET case TARGET-15-SJMPAL042789, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.8 years (1,371 days).
Specimen TARGET-15-SJMPAL042789-09A.3: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e7a2fa8-2bbf-4140-96dd-3e47086addb5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL042789-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL042789-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8a253352-42dd-4744-b55c-d41af1d54fc9

The open-access MAF lists 7 somatic variants for this specimen: 2 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 4, 3'UTR 1, Frame Shift Del 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2516A>G p.D839G | Missense Mutation (SNP) | VAF 88/179 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs991132188, COSV54045448; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.10492del p.A3498Lfs*4 | Frame Shift Del (DEL) | VAF 36/111 reads (32%) | called by mutect2, pindel, varscan2
- AKT1 | c.528C>T p.Y176= | Silent (SNP) | VAF 49/174 reads (28%) | catalogued as rs1422460834; ClinVar: likely benign; called by muse, mutect2, varscan2
- CC2D1A | c.657G>A p.A219= | Silent (SNP) | VAF 42/86 reads (49%) | catalogued as rs367628101; called by muse, mutect2, varscan2
- HNRNPCL2 | c.45C>T p.N15= | Silent (SNP) | VAF 89/174 reads (51%) | catalogued as rs1457502224; called by muse, mutect2, varscan2
- SYT10 | c.42G>A p.Q14= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs371830878; called by muse, mutect2, varscan2
- CLCNKB | c.*291T>C | 3'UTR (SNP) | VAF 16/68 reads (24%) | catalogued as rs1057855, COSV100989762; called by muse, varscan2
